Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70M, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70M-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology	Final Results
--------------------	---------------

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS: Adrenal, left (adrenalectomy): Pheochromocytoma, see Note.

NOTE: Immunohistochemistry is performed. Tumor cells are positive for chromogranin, synaptophysin, and CD56. S100 stains sustentacular cells.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief

Clinical History:

with left pheochromocytoma Specimen Taken For
Protocol: 01 - Yes

PROCEDURE: Pre-Operative Diagnosis: pheochromocytoma Post-Operative
Diagnosis:

same Operative Findings: large left adrenal mass

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, LEFT

GROSS DESCRIPTION: Received fresh labeled with the patient's name, medical record number, and further specified as "left adrenal" is a pink-yellow soft tissue fragment measuring 10.4 x 5.5 x 3.5 cm and weighing 62 grams. The external surface has an apparent orange rim of adrenal tissue measuring 4.6 x 1 x 0.5 cm. The external surface of the specimen is inked in black and bisected longitudinally revealing a brown-tan friable mass with hemorrhage and necrosis measuring 4.9 x 4 x 3.5 cm. Gross photographs are taken. Approximately 80% of viable-appearing tumor is procured for

Approximately 1 x 1 x 0.5 cm of grossly unreacted adrenal away from the mass is procured for the Laboratory of Pathology Tissue Bank.

Procurement is carried out by

at hour. The specimen received at the Laboratory of Pathology is grossly consistent with the above description. Representative sections of mass are submitted in white cassettes labeled for permanent processing. A representative section of grossly uninvolved adrenal is submitted in white cassette labeled for permanent processing.

Gross description dictated by

[page 2 of 2]
Surgical Pathology [

Final Results

No consultants

#

#

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file 58474c56-0c16-47b4-a073-de4cbd02552c (TCGA-QR-A70M.A5D2BBA1-2188-41DF-A32C-D916638267FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).